Gene-level copy-number profile of tumor specimen TCGA-13-1512-01A from TCGA case TCGA-13-1512, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.6 years (18,134 days).
Specimen TCGA-13-1512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.26516073-2e76-4c62-aeec-c2b40ae3ae2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1512-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3348520a-5fc1-4d93-900c-f2904498bfda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 24,274; copy number 2: 29,111; copy number 3: 3,971; copy number 4: 1,289; copy number 5: 445; copy number 6: 407; copy number 7: 280.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1512-01A-01D-0472-01): tumor purity 0.85, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:161,907,111–167,168,401, 35 genes: LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.
- chr5:167,287,320–167,309,870, 3 genes: AC091820.2, AC091820.1, AC008601.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,132 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:23,688,927–31,267,610, 76 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:35,429,064–35,429,277, 1 gene, copy number 6: U3.
- chr8:97,853,021–145,066,685, 755 genes, copy number 5–7 (broad region; genes not listed).
- chr10:16,521,714–18,940,953, 35 genes, copy number 5 (within-gene range 3–5): AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1.
- chr10:19,051,455–19,052,170, 1 gene, copy number 5: UBE2V2P1.
- chr12:13,000,451–29,784,759, 264 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,854. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
